Somatic mutation profile of tumor specimen TCGA-GN-A268-06A (aliquot TCGA-GN-A268-06A-11D-A196-08) from TCGA case TCGA-GN-A268, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 87.3 years (31,871 days).
Specimen TCGA-GN-A268-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 998b9cde-0948-4ba7-98cd-7f34ded1eb27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A268-10A (Blood Derived Normal), aliquot TCGA-GN-A268-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cfce933-f233-465f-9f89-3d438db3c49f

The open-access MAF lists 410 somatic variants for this specimen: 270 protein-altering or splice-affecting, 126 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 248, Silent 126, Nonsense Mutation 13, Intron 8, Splice Site 6, 3'UTR 2, Splice Region 2, 3'Flank 2, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 21/32 reads (66%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 58/129 reads (45%) | catalogued as rs74315343, CM000582, COSV62634573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 64/173 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AADACL4 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750445509, COSV66105821, COSV66106523; called by muse, mutect2, varscan2
- ABCA9 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV60620590; called by muse, mutect2, varscan2
- ABHD18 | c.436C>T p.P146S (on ENST00000398965 / NM_001039717.2; = p.P19S on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66293070; called by muse, mutect2, varscan2
- ADAMTS7 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.569); catalogued as rs373701558; called by muse, mutect2, varscan2
- ADCK2 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.093); catalogued as rs138501789; called by muse, mutect2, varscan2
- ADGRF1 | c.2117G>A p.G706D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51943897; called by muse, mutect2, varscan2
- ADGRF1 | c.1724C>G p.P575R | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs778881329, COSV51943913, COSV99032611; called by muse, mutect2, varscan2
- ADGRF5 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV51929767; called by muse, mutect2, varscan2
- ADGRG1 | c.1811A>T p.Q604L | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV65635185; called by muse, mutect2, varscan2
- ADGRG4 | c.2588C>T p.P863L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1288070711, COSV54949384; called by muse, mutect2, varscan2
- ADGRL2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752679138, COSV54649550; called by muse, mutect2, varscan2
- ADGRL2 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV54652364; called by muse, mutect2, varscan2
- ADGRV1 | c.6896C>T p.T2299I | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV67978498; called by muse, mutect2, varscan2
- ADNP2 | c.2627C>T p.T876I | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51536224; called by muse, mutect2, varscan2
- AL592490.1 | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs780270613, COSV69424515; called by muse, mutect2, varscan2
- ALMS1 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV52502758; called by muse, mutect2, varscan2
- AOAH | c.971G>A p.W324* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV51735711; called by muse, mutect2, varscan2
- APCS | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54817203; called by muse, mutect2, varscan2
- ARHGAP17 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 100/217 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773902428, COSV51504835; called by muse, mutect2, varscan2
- ARHGDIB | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57455289; called by muse, mutect2, varscan2
- ASB5 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.112); catalogued as COSV56668570; called by muse, mutect2, varscan2
- ASTN1 | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs944529041, COSV56061495; called by muse, mutect2, varscan2
- ATG4A | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 114/322 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57859326; called by muse, mutect2, varscan2
- ATP12A | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV54512311; called by muse, mutect2
- ATP6V1B1 | c.856C>T p.H286Y | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52268213; called by muse, mutect2, varscan2
- BCAS1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 111/232 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV65083800; called by muse, mutect2, varscan2
- BCORL1 | c.4612C>T p.L1538F | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54389581; called by muse, mutect2, varscan2
- BPTF | c.5803A>T p.T1935S | Missense Mutation (SNP) | VAF 126/175 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58831339; called by muse, mutect2, varscan2
- CACNA2D2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT tolerated (0.4); PolyPhen benign (0.246); catalogued as rs376677841; called by muse, varscan2
- CADM2 | c.577G>A p.D193N (on ENST00000407528 / NM_001167674.2; = p.D195N on NM_153184.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.231); catalogued as COSV67357714; called by muse, mutect2, varscan2
- CASKIN2 | c.2204G>A p.G735D | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV58592985; called by muse, mutect2, varscan2
- CBX4 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 11/18 reads (61%) | catalogued as COSV53964346, COSV99490630; called by muse, mutect2, varscan2
- CCDC185 | c.1758C>A p.F586L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.155); catalogued as COSV64820242; called by muse, mutect2, varscan2
- CCDC3 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.009); catalogued as rs764372915, COSV66560826; called by muse, mutect2, varscan2
- CCDC88B | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as rs1419370349, COSV57264856; called by muse, mutect2, varscan2
- CCKBR | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as rs765032135, COSV58098678; called by muse, mutect2, varscan2
- CD163 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63129466; called by muse, mutect2, varscan2
- CDH9 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV99142511; called by muse, mutect2, varscan2
- CDHR1 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV60559526; called by muse, mutect2, varscan2
- CDK13 | c.4039G>C p.A1347P | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as rs1488327247, COSV51696390; called by muse, mutect2, varscan2
- CEACAM19 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as COSV62551811; called by muse, mutect2, varscan2
- CEACAM4 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV55731820; called by muse, mutect2, varscan2
- CEACAM4 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs868982161, COSV55732527; called by muse, mutect2, varscan2
- CEP44 | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV56658438; called by muse, mutect2, varscan2
- CES3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV57592667; called by muse, mutect2, varscan2
- CFHR3 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV66401487; called by muse, mutect2, varscan2
- CHRNA3 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.926); catalogued as COSV58774039, COSV58774850; called by muse, mutect2, varscan2
- CIDEC | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs775071994, COSV100396649, COSV61061075; called by muse, mutect2, varscan2
- CLCN1 | c.2614G>A p.G872R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58370595; called by muse, mutect2, varscan2
- CLCN1 | c.2615G>A p.G872E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58367372; called by muse, mutect2, varscan2
- CLEC18B | c.676+1G>A p.X226_splice | Splice Site (SNP) | VAF 26/35 reads (74%) | catalogued as COSV60576517; called by muse, mutect2, varscan2
- CLEC4E | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.492); catalogued as rs759480111, COSV55224946; called by muse, mutect2, varscan2
- CLPP | c.556-2A>T p.X186_splice | Splice Site (SNP) | VAF 7/13 reads (54%) | catalogued as COSV55536089; called by muse, mutect2, varscan2
- CMTR2 | c.356A>C p.H119P | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV57602513; called by muse, mutect2, varscan2
- CNTN1 | c.2185-1G>A p.X729_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV61636172; called by muse, mutect2, varscan2
- COL25A1 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456984543, COSV101211282; called by muse, mutect2, varscan2
- COL4A4 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61629542; called by muse, mutect2, varscan2
- COL5A2 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); catalogued as COSV66407106; called by muse, mutect2, varscan2
- COX10 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1301537803, CM1312023, COSV55402179; called by muse, mutect2, varscan2
- COX4I2 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65781660; called by muse, mutect2, varscan2
- CPE | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.361); catalogued as COSV68579271; called by muse, mutect2, varscan2
- CPED1 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs768552123, COSV59997169; called by muse, mutect2, varscan2
- CPM | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs755183423, COSV104405381, COSV58031716; called by muse, mutect2, varscan2
- CPNE1 | c.1592C>T p.P531L (on ENST00000352393; = p.P536L on NM_003915.5) | Missense Mutation (SNP) | VAF 104/252 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV58289852; called by muse, mutect2, varscan2
- CPT1A | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as COSV55752831; called by muse, mutect2, varscan2
- CR1 | c.2651G>A p.G884E | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV65455867; called by muse, mutect2, varscan2
- CSMD2 | c.9521C>A p.P3174Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as COSV53879308; called by muse, mutect2
- CSMD3 | c.9205G>A p.E3069K (on ENST00000297405 / NM_001363185.1; = p.E2900K on NM_052900.3) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs1419786818, COSV52103232; called by muse, mutect2, varscan2
- CYP19A1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV53057084; called by muse, mutect2, varscan2
- CYP3A4 | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV60500956; called by muse, mutect2, varscan2
- DCC | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.319); catalogued as COSV59084468; called by muse, mutect2, varscan2
- DLC1 | c.2840C>T p.P947L (on ENST00000276297 / NM_001348081.2; = p.P510L on NM_006094.5) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as COSV52290393; called by muse, mutect2, varscan2
- DNAH6 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV52849792; called by muse, mutect2, varscan2
- DNAJC10 | c.1426T>A p.F476I | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899046; called by muse, mutect2, varscan2
- DOCK11 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761797003, COSV52233661; called by muse, mutect2, varscan2
- DOCK3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.574); catalogued as COSV56502883; called by muse, varscan2
- DOCK8 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV66632906; called by muse, mutect2, varscan2
- DPYD | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV60075134; called by muse, mutect2, varscan2
- DRC1 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55495570; called by muse, mutect2, varscan2
- ELAPOR2 | c.2549C>T p.S850L (on ENST00000450689 / NM_001142749.3; = p.S683L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as COSV51883817, COSV51884046; called by muse, mutect2, varscan2
- ESRP2 | c.1049G>C p.R350P (on ENST00000565858 / NM_001365264.1; = p.R340P on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV52171941; called by muse, mutect2, varscan2
- F8 | c.3026T>C p.L1009S | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV64269768; called by muse, mutect2, varscan2
- FAM170A | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as COSV58923940; called by muse, mutect2, varscan2
- FAT1 | c.13354C>A p.P4452T | Missense Mutation (SNP) | VAF 173/366 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as COSV71671933; called by muse, mutect2, varscan2
- FAT4 | c.5879G>A p.G1960E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs752661300, COSV58671577; called by muse, mutect2, varscan2
- FCGBP | c.8900C>T p.S2967F | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs1413842575; called by muse, varscan2
- FLG | c.5579G>A p.G1860E | Missense Mutation (SNP) | VAF 206/423 reads (49%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV64236486; called by muse, mutect2, varscan2
- FLG | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs751519390, COSV64236489; called by muse, mutect2, varscan2
- FPR2 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs200923071, COSV60671898; called by muse, mutect2, varscan2
- FRAS1 | c.3991C>T p.Q1331* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV53589207; called by muse, mutect2, varscan2
- FUT9 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.755); catalogued as rs146406553, COSV56142363; called by muse, mutect2, varscan2
- FYB2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as COSV58582912; called by muse, mutect2, varscan2
- GFRAL | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs868599487, COSV61228767, COSV61234756; called by muse, mutect2, varscan2
- GK2 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62626100; called by muse, mutect2, varscan2
- GLCE | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV55944310, COSV99962342; called by muse, mutect2, varscan2
- GLYR1 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV58925562; called by muse, mutect2, varscan2
- GNL3L | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV60575344; called by muse, mutect2, varscan2
- GRHL1 | c.1088G>A p.W363* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100257663; called by muse, mutect2, varscan2
- GRXCR1 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as rs779053724, COSV67670076; called by muse, mutect2, varscan2
- GUCA1A | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV50003456; called by muse, mutect2, varscan2
- GUCY1A1 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV56649126; called by muse, mutect2, varscan2
- HCRTR2 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs201301558, COSV63793801, COSV63798056, COSV63799846; called by muse, mutect2, varscan2
- HIPK2 | c.3395A>G p.Q1132R | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.775); catalogued as COSV69211599; called by muse, mutect2, varscan2
- HIPK2 | c.3394C>T p.Q1132* | Nonsense Mutation (SNP) | VAF 19/25 reads (76%) | catalogued as COSV101301622; called by mutect2, varscan2
- HNRNPCL1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58609764; called by muse, mutect2, varscan2
- HTR2A | c.453G>A p.W151* | Nonsense Mutation (SNP) | VAF 84/170 reads (49%) | catalogued as COSV66326629; called by muse, mutect2, varscan2
- HTR3A | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 115/133 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55467945; called by muse, mutect2, varscan2
- HTR5A | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.292); catalogued as rs766782274, COSV55280330, COSV55280443; called by muse, mutect2, varscan2
- IL36A | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 122/212 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV52082639; called by muse, mutect2, varscan2
- INSYN1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs149206275, COSV65837120; called by muse, mutect2, varscan2
- IRAK3 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV54159392; called by muse, mutect2, varscan2
- ISM1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV52602503, COSV52608802; called by muse, mutect2
- ITGB1BP2 | c.539+1G>A p.X180_splice | Splice Site (SNP) | VAF 28/66 reads (42%) | catalogued as COSV52135713; called by muse, mutect2, varscan2
- IZUMO1R | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 97/185 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs184112650; called by muse, mutect2, varscan2
- KCND2 | c.1543C>T p.H515Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.426); catalogued as COSV58569415; called by muse, mutect2, varscan2
- KCNH7 | c.2154+8T>C | Splice Region (SNP) | VAF 47/87 reads (54%) | catalogued as COSV100034885; called by muse, mutect2, varscan2
- KCNQ3 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 41/97 reads (42%) | catalogued as COSV66463751; called by muse, mutect2, varscan2
- KIRREL1 | c.2261A>T p.Q754L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63285306; called by muse, mutect2, varscan2
- KIZ | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs6075771, COSV55683565; called by muse, mutect2, varscan2
- KLHL18 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99230685; called by muse, mutect2, varscan2
- KLKB1 | c.1784T>A p.I595N | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52993892; called by muse, mutect2, varscan2
- KRT13 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as COSV55839031; called by muse, mutect2, varscan2
- KRT25 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1210378338, COSV56443636; called by muse, mutect2, varscan2
- KRT77 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV59238401; called by muse, mutect2, varscan2
- LCA5 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 63/65 reads (97%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV63970513; called by muse, mutect2, varscan2
- LDB2 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 154/330 reads (47%) | catalogued as COSV58762586; called by muse, mutect2, varscan2
- LRATD2 | c.346T>A p.C116S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV59229787; called by muse, mutect2, varscan2
- LRP1B | c.6429G>A p.G2143= | Splice Region (SNP) | VAF 7/24 reads (29%) | catalogued as COSV67186589; called by muse, mutect2, varscan2
- LRRC4 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV50813227; called by muse, mutect2, varscan2
- MAGEB6 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV66871810; called by muse, mutect2, varscan2
- MAGEB6 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 93/117 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV66871817; called by muse, mutect2, varscan2
- MAGEE2 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs765658489, COSV64897255; called by muse, mutect2, varscan2
- MAST1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295257142, COSV52241016; called by muse, mutect2, varscan2
- MAST3 | c.3775C>G p.R1259G | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV53217469, COSV53227986; called by muse, mutect2, varscan2
- MCTP2 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.229); catalogued as COSV59140725; called by muse, varscan2
- MDFI | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV57821560; called by muse, mutect2, varscan2
- MERTK | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV54924560; called by muse, mutect2, varscan2
- MIPEP | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66299623; called by muse, mutect2, varscan2
- MKX | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV65391461, COSV65391744; called by muse, mutect2, varscan2
- MMRN2 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as rs1234489479, COSV64400375; called by muse, mutect2, varscan2
- MTF1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1341140702, COSV65988339; called by muse, mutect2, varscan2
- MTNR1A | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1483013458, COSV56154949, COSV56157519; called by muse, mutect2, varscan2
- MUC16 | c.2911A>G p.S971G | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as rs372171885; called by muse, mutect2, varscan2
- MXRA5 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54222236; called by muse, mutect2, varscan2
- MYH2 | c.3264-1G>A p.X1088_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | catalogued as COSV55431613; called by muse, mutect2, varscan2
- MYH8 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101238448, COSV67959805; called by muse, mutect2, varscan2
- MYO1A | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs773347648, COSV55651754; called by muse, varscan2
- MYO1F | c.3196G>A p.E1066K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs777571005, COSV57791838; called by muse, mutect2, varscan2
- MYOF | c.2917T>C p.W973R | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63700259; called by muse, mutect2, varscan2
- MYOM2 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.343); catalogued as rs866754933, COSV100037111; called by muse, mutect2, varscan2
- MYOM2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.284); catalogued as rs564509220, COSV50789846; called by muse, mutect2, varscan2
- NCAPD2 | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 97/213 reads (46%) | catalogued as rs550146120, COSV59697728; called by muse, mutect2, varscan2
- NEXMIF | c.3328G>A p.E1110K | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV50021799; called by muse, mutect2, varscan2
- NEXMIF | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV50021645; called by muse, mutect2, varscan2
- NLGN3 | c.1045G>A p.V349M (on ENST00000358741 / NM_181303.2; = p.V329M on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62441688; called by muse, mutect2, varscan2
- NLRP11 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV64085665; called by muse, mutect2, varscan2
- NLRP12 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV60743566; called by muse, mutect2, varscan2
- NOS2 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV58221702; called by muse, mutect2, varscan2
- NOTCH4 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 241/503 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as rs144962111; called by muse, mutect2, varscan2
- NPFFR2 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs560342317, COSV58146315; called by muse, mutect2, varscan2
- NUFIP2 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 39/92 reads (42%) | catalogued as COSV99837299; called by muse, mutect2, varscan2
- NXPE4 | c.1130G>A p.G377E (on ENST00000375478 / NM_001077639.2; = p.G93E on NM_017678.3) | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs945992162, COSV64943396; called by muse, mutect2, varscan2
- OR10G4 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 65/95 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.078); catalogued as rs267602750, COSV57976590; called by muse, mutect2, varscan2
- OR10H1 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.651); catalogued as COSV58470710; called by muse, mutect2, varscan2
- OR51S1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59057209, COSV59058640; called by muse, mutect2, varscan2
- OR51T1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs867447772, COSV59023663, COSV59026348; called by muse, mutect2, varscan2
- OR52A5 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as rs753380946, COSV56614199; called by muse, mutect2, varscan2
- OR52A5 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs868264919, COSV56614214; called by muse, mutect2, varscan2
- OR7D2 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60138817; called by muse, mutect2, varscan2
- OR9K2 | c.589C>T p.R197W (on ENST00000305377; = p.R175W on NM_001005243.1) | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs748250309, COSV59531351; called by muse, mutect2, varscan2
- OSMR | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs867485740, COSV57080986; called by muse, mutect2, varscan2
- OTOF | c.1937G>A p.G646D | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV55495582; called by muse, mutect2, varscan2
- OXTR | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765091883, COSV57478383; called by muse, mutect2, varscan2
- PASD1 | c.233T>C p.L78S | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV64854091; called by muse, mutect2, varscan2
- PCDH18 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as COSV61266399; called by muse, mutect2, varscan2
- PCDHB12 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as rs782727446, COSV53392661, COSV99078365; called by muse, mutect2, varscan2
- PCDHB5 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.436); catalogued as COSV50647316; called by muse, mutect2, varscan2
- PCLO | c.11686C>T p.P3896S | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV61616189; called by muse, mutect2, varscan2
- PCLO | c.6919G>A p.E2307K | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV61616198; called by muse, mutect2, varscan2
- PCLO | c.5321C>T p.S1774L | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61616208; called by muse, mutect2, varscan2
- PDE4A | c.833G>A p.R278K (on ENST00000380702 / NM_001111307.2; = p.R39K on NM_006202.3) | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV53350798; called by muse, mutect2, varscan2
- PHACTR2 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV59850258; called by muse, mutect2, varscan2
- PHF8 | c.2366G>A p.R789Q (on ENST00000357988 / NM_001184896.1; = p.R753Q on NM_015107.3) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1263803925, COSV57677476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKD1 | c.12355C>T p.R4119W (on ENST00000262304 / NM_001009944.3; = p.R4118W on NM_000296.4) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs889547396, COSV99237589; called by muse, mutect2, varscan2
- PKHD1L1 | c.4825G>A p.E1609K | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV65737078; called by muse, mutect2, varscan2
- PLA2G4F | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1213557740, COSV51825456; called by muse, mutect2
- PLEKHG4 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs760689398, COSV64611747; called by muse, mutect2, varscan2
- PRAME | c.923T>C p.F308S | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV67160953; called by muse, mutect2, varscan2
- PRPS1L1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs768761052, COSV72649805; called by muse, mutect2, varscan2
- PRPS1L1 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV72649807, COSV72650040; called by muse, mutect2, varscan2
- PRR14L | c.6059C>T p.P2020L | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57882813, COSV57886442; called by muse, mutect2, varscan2
- PTCHD3 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1564808227, COSV71256284; called by muse, mutect2, varscan2
- PTPRB | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs184275696, COSV54232350, COSV99715331; called by muse, mutect2, varscan2
- PTPRB | c.390G>A p.W130* | Nonsense Mutation (SNP) | VAF 25/44 reads (57%) | catalogued as rs867417732, COSV51724902; called by muse, mutect2, varscan2
- PWWP3B | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs371293435, COSV61798287; called by muse, mutect2, varscan2
- PYHIN1 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV63721293; called by muse, mutect2, varscan2
- RAB11FIP1 | c.373T>G p.W125G | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54758189; called by muse, mutect2, varscan2
- RAB9B | c.403A>C p.T135P | Missense Mutation (SNP) | VAF 90/266 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54587144; called by muse, mutect2, varscan2
- RAI1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV55389003; called by muse, mutect2, varscan2
- RAMP3 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs749634715, COSV54244744; called by muse, mutect2, varscan2
- RBFA | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.472); catalogued as COSV51532849; called by muse, mutect2, varscan2
- SALL4 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53849806; called by muse, mutect2, varscan2
- SAMD7 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as COSV59416883; called by muse, mutect2, varscan2
- SCN10A | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as rs77049337, COSV71860249; called by muse, mutect2, varscan2
- SCN1A | c.2087C>T p.S696F (on ENST00000303395 / NM_001202435.3; = p.S685F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV57660055, COSV57682848; called by muse, mutect2, varscan2
- SCNN1A | c.858G>C p.Q286H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.776); catalogued as COSV57434013; called by muse, mutect2, varscan2
- SDR16C5 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV58125353; called by muse, mutect2, varscan2
- SEMA6D | c.1469T>A p.L490* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV60372796; called by muse, mutect2, varscan2
- SH2B1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV100450959; called by muse, mutect2, varscan2
- SHANK1 | c.1944G>A p.M648I | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs767092528, COSV53243012; called by muse, mutect2, varscan2
- SLC9C1 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV59885024; called by muse, mutect2, varscan2
- SLCO1B3 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.913); catalogued as COSV53932263; called by muse, mutect2
- SLIT2 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.136); catalogued as COSV56560191; called by muse, mutect2, varscan2
- SMAD1 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57470148; called by muse, mutect2, varscan2
- SMCHD1 | c.4517G>A p.R1506H | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs756166672, COSV55251590; called by muse, mutect2, varscan2
- SNAP91 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV52115118; called by muse, mutect2, varscan2
- SORCS3 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as COSV63802764, COSV63807620; called by muse, mutect2, varscan2
- SPAG9 | c.3623C>T p.P1208L (on ENST00000262013 / NM_001130528.3; = p.P1194L on NM_003971.6) | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56231117; called by muse, varscan2
- SPATA18 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.618); catalogued as COSV54641633, COSV99730861; called by muse, mutect2, varscan2
- SPATA31E1 | c.3835G>A p.G1279R | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57789521; called by muse, mutect2, varscan2
- SPATA6 | c.781-2A>G p.X261_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as rs1461856980, COSV64056409; called by muse, mutect2
- SPHKAP | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60868618; called by muse, mutect2, varscan2
- SPOCD1 | c.320T>G p.V107G | Missense Mutation (SNP) | VAF 74/122 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV57093739; called by muse, mutect2, varscan2
- SPTA1 | c.6613G>A p.E2205K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1451799101, COSV63748982; called by muse, mutect2, varscan2
- STAB1 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs770356720, COSV58732145, COSV58737116; called by muse, mutect2, varscan2
- STRIP1 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as rs1484416853, COSV63929702; called by muse, mutect2, varscan2
- SUZ12 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.306); catalogued as COSV59498063; called by muse, mutect2, varscan2
- SYT7 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV55653917; called by muse, mutect2, varscan2
- SYTL4 | c.1525T>C p.S509P | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52165378; called by muse, mutect2, varscan2
- TBX3 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.543); catalogued as COSV57469268; called by muse, mutect2, varscan2
- THAP4 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as COSV67190660; called by muse, mutect2, varscan2
- THSD7B | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55654466; called by muse, mutect2, varscan2
- TLL1 | c.1832G>A p.R611K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50261990; called by muse, mutect2, varscan2
- TM4SF20 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749131459, COSV58818441; called by muse, mutect2, varscan2
- TMC5 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.988); catalogued as COSV66864449; called by muse, mutect2, varscan2
- TMEM38A | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs147713228; called by muse, mutect2, varscan2
- TPO | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61094871; called by muse, mutect2, varscan2
- TRIM28 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as rs757143187, COSV99448845; called by muse, mutect2, varscan2
- TRIM28 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV99448848; called by muse, mutect2, varscan2
- TRPC4 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.987); catalogued as rs757115113, COSV58990602; called by muse, mutect2, varscan2
- TTN | c.61363G>A p.E20455K (on ENST00000591111; = p.E13031K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | PolyPhen possibly damaging (0.654); catalogued as COSV59887757; called by muse, mutect2, varscan2
- TTN | c.50941G>A p.D16981N (on ENST00000591111; = p.D9557N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | PolyPhen benign (0.043); catalogued as rs377683368; called by muse, mutect2, varscan2
- TTN | c.15767T>A p.I5256N (on ENST00000591111; = p.I4329N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | PolyPhen probably damaging (0.974); catalogued as COSV59887814; called by muse, mutect2, varscan2
- TTN | c.8008G>A p.D2670N (on ENST00000591111; = p.D2624N on NM_003319.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | PolyPhen benign (0.011); catalogued as rs1344075805, COSV59877062; called by muse, mutect2, varscan2
- TTN | c.6275G>A p.G2092E (on ENST00000591111; = p.G2046E on NM_003319.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | PolyPhen possibly damaging (0.714); catalogued as COSV59887856; called by muse, mutect2, varscan2
- TUBA8 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV57812307; called by muse, mutect2, varscan2
- UGT2B17 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1351493392, COSV58500798; called by muse, mutect2, varscan2
- VSTM4 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.702); catalogued as COSV60524337; called by muse, mutect2, varscan2
- WDR33 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs763755772, COSV59246220; called by muse, mutect2, varscan2
- WDR81 | c.3448G>C p.E1150Q (on ENST00000409644 / NM_001163809.2; = p.E99Q on NM_152348.4) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.964); catalogued as COSV58478472; called by muse, mutect2, varscan2
- XIRP2 | c.3010G>A p.G1004R (on ENST00000628543; = p.G1179R on NM_152381.6) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs867783511, COSV54682768; called by muse, mutect2, varscan2
- XKR3 | c.1074G>A p.M358I | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs866720137, COSV58884706; called by muse, mutect2, varscan2
- ZBTB46 | c.1175G>A p.G392D | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs1479098887, COSV55506760; called by muse, mutect2, varscan2
- ZEB2 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57951439; called by muse, mutect2, varscan2
- ZFAND2A | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV57179901; called by muse, mutect2, varscan2
- ZMIZ2 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54805987; called by muse, mutect2, varscan2
- ZNF26 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1455440776; called by muse, mutect2, varscan2
- ZNF283 | c.1421T>C p.L474P | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61030429; called by muse, mutect2, varscan2
- ZNF416 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52183407; called by muse, mutect2, varscan2
- ZNF512 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs777748825, COSV62673778; called by muse, mutect2, varscan2
- ZNF670 | c.742A>T p.T248S | Missense Mutation (SNP) | VAF 45/47 reads (96%) | SIFT tolerated (0.14); PolyPhen benign (0.278); catalogued as COSV63607618; called by muse, mutect2, varscan2
- ZNF700 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV54310844, COSV99583864; called by muse, mutect2, varscan2
- ADAMTS20 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCL14 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR11H1 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.127); called by mutect2, varscan2
- TRBV4-2 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ACSM1 | c.873C>T p.I291= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs867962448, COSV54633006; called by muse, mutect2, varscan2
- ADAMTS6 | c.963C>T p.S321= | Silent (SNP) | VAF 28/28 reads (100%) | catalogued as COSV66856759; called by muse, mutect2, varscan2
- ADGRF5 | c.3021C>A p.L1007= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV51929759; called by muse, mutect2, varscan2
- AL121899.2 | c.1224C>T p.I408= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as COSV67349697; called by muse, mutect2, varscan2
- ALDH8A1 | c.264C>T p.A88= | Silent (SNP) | VAF 58/63 reads (92%) | catalogued as COSV55640161; called by muse, mutect2, varscan2
- ANK3 | c.7824C>T p.S2608= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55044268; called by muse, mutect2, varscan2
- ATCAY | c.441C>T p.S147= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs771736539, COSV56654170; called by muse, mutect2, varscan2
- ATP1A3 | c.2109C>T p.I703= (on ENST00000545399 / NM_001256214.2; = p.I690= on NM_152296.5) | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV57485071; called by muse, mutect2, varscan2
- ATP7A | c.843C>T p.F281= | Silent (SNP) | VAF 75/183 reads (41%) | catalogued as COSV58442728; called by muse, mutect2, varscan2
- ATXN7L3 | c.741C>T p.V247= (on ENST00000389384 / NM_001382309.1; = p.V254= on NM_001382308.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV60228117; called by muse, mutect2, varscan2
- AUTS2 | c.3198C>T p.F1066= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV61383268; called by muse, mutect2, varscan2
- BRWD3 | c.1359C>T p.I453= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV64743927; called by muse, mutect2, varscan2
- C6 | c.2244G>A p.G748= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV54704890; called by muse, mutect2, varscan2
- CCDC3 | c.645G>A p.R215= | Silent (SNP) | VAF 53/66 reads (80%) | catalogued as COSV101121652; called by muse, mutect2, varscan2
- CDH23 | c.558C>T p.I186= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV54924453; called by muse, mutect2, varscan2
- CHAT | c.1560G>A p.G520= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV60320205; called by muse, mutect2, varscan2
- CHRM3 | c.48C>T p.I16= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV55080214; called by muse, mutect2, varscan2
- CLVS1 | c.603C>T p.I201= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs967257201, COSV57970598; called by muse, mutect2, varscan2
- CLVS2 | c.333G>A p.L111= | Silent (SNP) | VAF 54/56 reads (96%) | catalogued as rs1357460065, COSV51558753, COSV99253765; called by muse, mutect2, varscan2
- COL6A3 | c.4677C>T p.F1559= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs147215386; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CPED1 | c.2307G>A p.R769= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV59997184; called by muse, mutect2, varscan2
- CYP2C19 | c.666C>T p.I222= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs267602635, COSV64906778; called by muse, mutect2, varscan2
- CYP4B1 | c.192G>A p.T64= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs760448256, COSV54721123, COSV99597149; called by muse, mutect2, varscan2
- CYP4F22 | c.930C>T p.L310= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV54106523; called by muse, mutect2, varscan2
- DNAH10 | c.6057C>T p.I2019= (on ENST00000409039; = p.I1958= on NM_207437.3) | Silent (SNP) | VAF 36/41 reads (88%) | catalogued as rs1368614996, COSV68987855; called by muse, mutect2, varscan2
- DNAH9 | c.10641C>A p.P3547= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV52334125; called by muse, mutect2, varscan2
- DNAJB12 | c.672C>T p.F224= (on ENST00000338820; = p.F190= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV58759550; called by muse, mutect2, varscan2
- DNAJC10 | c.1425C>T p.F475= | Silent (SNP) | VAF 57/194 reads (29%) | catalogued as COSV51135725, COSV51149236; called by muse, mutect2, varscan2
- DSC2 | c.720C>T p.Y240= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV51861088; called by muse, mutect2, varscan2
- EZHIP | c.894C>T p.V298= | Silent (SNP) | VAF 13/13 reads (100%) | catalogued as rs1246378838, COSV100539584; called by muse, mutect2, varscan2
- F8 | c.1665C>T p.F555= | Silent (SNP) | VAF 59/115 reads (51%) | catalogued as rs199902295, COSV64269422; called by muse, mutect2, varscan2
- FBXL7 | c.849C>T p.F283= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV61641244; called by muse, mutect2, varscan2
- FCRL4 | c.462C>T p.I154= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV54859718; called by muse, mutect2, varscan2
- FOS | c.474G>A p.R158= | Silent (SNP) | VAF 12/13 reads (92%) | catalogued as COSV57839021; called by muse, mutect2, varscan2
- GBA3 | c.1377C>T p.I459= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV72437847; called by muse, mutect2, varscan2
- GPR82 | c.72C>T p.L24= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as COSV56886646; called by muse, mutect2, varscan2
- GPRC5B | c.207C>T p.I69= | Silent (SNP) | VAF 48/85 reads (56%) | catalogued as COSV56025096; called by muse, mutect2, varscan2
- GPRC6A | c.219A>G p.Q73= | Silent (SNP) | VAF 16/17 reads (94%) | catalogued as rs373303273; called by muse, mutect2, varscan2
- GRK3 | c.57G>A p.K19= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV60793345; called by muse, mutect2, varscan2
- HTT | c.7863C>T p.S2621= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs922172958, COSV61857385; called by muse, mutect2, varscan2
- IQSEC2 | c.1584C>T p.S528= (on ENST00000642864 / NM_001111125.3; = p.S323= on NM_015075.2) | Silent (SNP) | VAF 87/95 reads (92%) | catalogued as COSV64723511; called by muse, mutect2, varscan2
- IQSEC3 | c.1851C>T p.A617= (on ENST00000538872 / NM_001170738.2; = p.A314= on NM_015232.1) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV58280568; called by muse, mutect2
- IRGQ | c.1737C>T p.F579= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1215943714, COSV60670163; called by muse, mutect2, varscan2
- ISM2 | c.1395G>A p.L465= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as COSV53633869; called by muse, mutect2, varscan2
- KCNB2 | c.1911C>T p.L637= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV73048906; called by muse, mutect2, varscan2
- KCND3 | c.966C>T p.G322= | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as COSV56175025; called by muse, mutect2, varscan2
- KCNH5 | c.885C>T p.I295= | Silent (SNP) | VAF 15/16 reads (94%) | catalogued as rs1230839550, COSV59752184; called by muse, mutect2, varscan2
- KIAA0319 | c.2568G>A p.K856= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV65496288; called by muse, mutect2, varscan2
- KIAA1217 | c.495G>A p.R165= | Silent (SNP) | VAF 27/28 reads (96%) | catalogued as COSV64600553; called by muse, mutect2, varscan2
- KLF4 | c.1353G>A p.T451= | Silent (SNP) | VAF 45/47 reads (96%) | catalogued as rs774893122, COSV65928605; called by muse, mutect2, varscan2
- KLK12 | c.171C>G p.V57= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV51575694; called by muse, mutect2, varscan2
- KSR2 | c.2346C>T p.I782= | Silent (SNP) | VAF 20/23 reads (87%) | catalogued as COSV56665748; called by muse, mutect2, varscan2
- LCN2 | c.558C>T p.I186= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as rs567005154, COSV52979490; called by muse, mutect2, varscan2
- LEPR | c.2925G>A p.E975= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100848063, COSV62745612; called by muse, mutect2, varscan2
- LPO | c.1836G>A p.G612= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV51856843; called by muse, mutect2, varscan2
- LRRC32 | c.285C>T p.A95= | Silent (SNP) | VAF 59/110 reads (54%) | catalogued as COSV52631464; called by muse, mutect2, varscan2
- LYPLA2 | c.150T>C p.P50= | Silent (SNP) | VAF 53/80 reads (66%) | catalogued as COSV55754386; called by muse, mutect2, varscan2
- MLNR | c.855C>T p.A285= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs1226208101, COSV54531670; called by muse, mutect2, varscan2
- MMP1 | c.219G>C p.L73= | Silent (SNP) | VAF 46/69 reads (67%) | catalogued as COSV59509381; called by muse, mutect2, varscan2
- MRPL18 | c.186C>A p.A62= | Silent (SNP) | VAF 35/35 reads (100%) | catalogued as COSV58457460; called by muse, mutect2, varscan2
- MYH4 | c.1698C>T p.F566= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs746159729, COSV55112281; called by muse, mutect2, varscan2
- MYO1B | c.282C>T p.S94= | Silent (SNP) | VAF 129/248 reads (52%) | catalogued as COSV58427060; called by muse, mutect2, varscan2
- MYO1H | c.1167G>A p.R389= | Silent (SNP) | VAF 85/95 reads (89%) | catalogued as rs745952165, COSV60442979; called by muse, varscan2
- MYO3A | c.4791C>T p.Y1597= | Silent (SNP) | VAF 32/35 reads (91%) | catalogued as rs779121070, COSV52150643; called by muse, mutect2, varscan2
- NLRP11 | c.255C>T p.I85= | Silent (SNP) | VAF 57/110 reads (52%) | catalogued as COSV64085668; called by muse, mutect2, varscan2
- NLRP3 | c.705G>A p.R235= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as rs777071745, COSV60220001; called by muse, mutect2, varscan2
- NLRP5 | c.3543C>T p.V1181= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as rs755361044, COSV66762077; called by muse, mutect2, varscan2
- NLRP9 | c.1110C>T p.S370= | Silent (SNP) | VAF 66/108 reads (61%) | catalogued as COSV60459556; called by muse, mutect2, varscan2
- NNMT | c.582G>A p.V194= | Silent (SNP) | VAF 33/39 reads (85%) | catalogued as rs373225428, COSV55472904; called by muse, mutect2, varscan2
- NPAS4 | c.843G>A p.V281= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as rs373935651; called by muse, mutect2, varscan2
- NUFIP2 | c.1197C>T p.S399= | Silent (SNP) | VAF 39/92 reads (42%) | catalogued as COSV99837301; called by muse, mutect2, varscan2
- OR10A7 | c.75T>A p.V25= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV58277721; called by muse, mutect2, varscan2
- OR10AG1 | c.303G>A p.T101= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs774639849, COSV56631456; called by muse, mutect2, varscan2
- OR11L1 | c.402C>T p.F134= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV63313601; called by muse, mutect2, varscan2
- OR13H1 | c.921G>A p.R307= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV58547057; called by muse, mutect2, varscan2
- OR1J4 | c.798C>T p.A266= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as COSV61589516; called by muse, mutect2, varscan2
- OR4B1 | c.207C>T p.I69= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as COSV58881975; called by muse, mutect2, varscan2
- OR4K2 | c.183C>T p.F61= | Silent (SNP) | VAF 65/242 reads (27%) | catalogued as COSV53848119; called by muse, mutect2, varscan2
- OR51A2 | c.642C>T p.L214= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as COSV66748118; called by muse, mutect2, varscan2
- OR6B3 | c.903G>A p.L301= | Silent (SNP) | VAF 122/243 reads (50%) | catalogued as COSV60112648; called by muse, mutect2, varscan2
- OR6K3 | c.744G>A p.G248= (on ENST00000368146; = p.G232= on NM_001005327.2) | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV63745274; called by muse, mutect2, varscan2
- PCLO | c.14517C>T p.S4839= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV61616178; called by muse, mutect2, varscan2
- PFAS | c.1125T>C p.F375= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV58978441; called by muse, mutect2, varscan2
- PILRA | c.291C>T p.L97= | Silent (SNP) | VAF 96/184 reads (52%) | catalogued as COSV52199178; called by muse, mutect2, varscan2
- PKD1 | c.12354C>T p.Y4118= (on ENST00000262304 / NM_001009944.3; = p.Y4117= on NM_000296.4) | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV99237592; called by muse, mutect2, varscan2
- PKHD1L1 | c.3402C>T p.S1134= | Silent (SNP) | VAF 61/126 reads (48%) | catalogued as COSV65737074; called by muse, mutect2, varscan2
- PLD5 | c.1524G>A p.P508= (on ENST00000442594; = p.P446= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 99/205 reads (48%) | catalogued as rs771508493, COSV59133616; called by muse, mutect2, varscan2
- POSTN | c.1272C>T p.L424= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs1375580316, COSV65711866; called by muse, mutect2, varscan2
- PPIP5K2 | c.1521G>A p.L507= | Silent (SNP) | VAF 31/33 reads (94%) | catalogued as rs1554214271, COSV58602483; called by muse, mutect2, varscan2
- PRDM2 | c.2781C>T p.L927= | Silent (SNP) | VAF 64/140 reads (46%) | catalogued as rs747698621, COSV52442860; called by muse, mutect2, varscan2
- PRRG3 | c.498G>A p.R166= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV64850704; called by muse, mutect2, varscan2
- RFTN1 | c.687G>A p.G229= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV61916789; called by muse, mutect2, varscan2
- RIMBP3 | c.3402G>A p.K1134= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- ROBO1 | c.3348C>T p.I1116= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs755609179, COSV71391689; called by muse, mutect2, varscan2
- RXFP1 | c.1893C>T p.F631= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs748504998, COSV104410571, COSV57046768; called by muse, mutect2, varscan2
- SCN10A | c.3072G>A p.V1024= | Silent (SNP) | VAF 49/86 reads (57%) | catalogued as rs750273256, COSV71860247; called by muse, mutect2, varscan2
- SCN11A | c.2715G>A p.K905= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV56565749; called by muse, mutect2, varscan2
- SCRN2 | c.483C>T p.F161= | Silent (SNP) | VAF 77/213 reads (36%) | catalogued as COSV51634901; called by muse, mutect2, varscan2
- SH2B1 | c.1056C>T p.S352= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs772213283, COSV59466323; called by muse, mutect2, varscan2
- SIGLEC12 | c.948C>T p.S316= (on ENST00000291707 / NM_053003.4; = p.S198= on NM_033329.2) | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV52459341; called by muse, mutect2, varscan2
- SLC2A10 | c.723C>T p.F241= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV63713694, COSV63714561; called by muse, mutect2, varscan2
- SLC35F3 | c.642C>T p.A214= (on ENST00000366617 / NM_001300845.1; = p.A283= on NM_173508.4) | Silent (SNP) | VAF 204/424 reads (48%) | catalogued as rs766554123, COSV64018238; called by muse, mutect2, varscan2
- SLC5A7 | c.126C>T p.I42= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV50888908; called by muse, mutect2, varscan2
- SLCO2A1 | c.1137G>A p.G379= | Silent (SNP) | VAF 18/18 reads (100%) | catalogued as COSV60483559; called by muse, mutect2, varscan2
- SORCS3 | c.3300G>A p.G1100= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV63802765, COSV63814647; called by muse, mutect2, varscan2
- SRCAP | c.6957C>T p.F2319= | Silent (SNP) | VAF 59/118 reads (50%) | catalogued as COSV52667522; called by muse, mutect2, varscan2
- TECTB | c.201T>C p.G67= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV65594612; called by muse, mutect2
- TIFAB | c.114C>T p.L38= | Silent (SNP) | VAF 42/48 reads (88%) | catalogued as rs750046236, COSV72345650; called by muse, mutect2, varscan2
- TMEM236 | c.162T>A p.S54= | Silent (SNP) | VAF 320/354 reads (90%) | called by muse, varscan2
- TNFRSF21 | c.930G>A p.L310= | Silent (SNP) | VAF 98/366 reads (27%) | catalogued as COSV57280098; called by muse, mutect2, varscan2
- TRBV5-1 | c.93C>T p.I31= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- TRIM67 | c.2001C>T p.A667= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as rs1336434065, COSV64158095; called by muse, mutect2
- TSHZ2 | c.777G>A p.R259= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV61586834, COSV61588365; called by muse, mutect2, varscan2
- TTN | c.71916C>T p.I23972= (on ENST00000591111; = p.I16548= on NM_003319.4) | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV59887723; called by muse, mutect2, varscan2
- TTN | c.33597G>A p.V11199= (on ENST00000591111; = p.V10272= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60189391; called by mutect2, varscan2
- UGDH | c.54C>G p.P18= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV57096630; called by muse, mutect2, varscan2
- UMODL1 | c.2940C>T p.P980= (on ENST00000408910 / NM_001004416.2; = p.P1108= on NM_173568.3) | Silent (SNP) | VAF 33/34 reads (97%) | catalogued as COSV68569265; called by muse, mutect2, varscan2
- YDJC | c.948C>T p.P316= | Silent (SNP) | VAF 77/202 reads (38%) | catalogued as rs1188840258, COSV53037135; called by muse, mutect2, varscan2
- ZBTB12 | c.639G>T p.V213= | Silent (SNP) | VAF 246/570 reads (43%) | catalogued as COSV64993548; called by muse, mutect2, varscan2
- ZBTB40 | c.3510C>T p.A1170= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1214819566, COSV65144613; called by muse, mutect2, varscan2
- ZC3H4 | c.2134C>T p.L712= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs915176380, COSV53410491; called by muse, mutect2, varscan2
- ZNF215 | c.1383C>T p.F461= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV53491646, COSV99550013; called by muse, mutect2, varscan2
- ZNF407 | c.4884T>C p.F1628= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV55242822; called by muse, mutect2, varscan2
- ZNF676 | c.813C>T p.I271= (on ENST00000650058; = p.I239= on NM_001001411.3) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1306332378, COSV68092165; called by muse, mutect2, varscan2
- ZNF804A | c.358C>T p.L120= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56435596; called by muse, mutect2, varscan2
- ZZEF1 | c.1008C>T p.I336= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV67555941; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848274 G>A | 5'Flank (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- BCL11A | c.386-6405A>G | Intron (SNP) | VAF 347/638 reads (54%) | catalogued as COSV59624373; called by muse, mutect2, varscan2
- CALB2 | c.*2G>A | 3'UTR (SNP) | VAF 26/29 reads (90%) | catalogued as COSV100226148, COSV56940098; called by muse, mutect2, varscan2
- CCSER1 | c.2011-35305G>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs867764661, COSV100389378; called by muse, mutect2, varscan2
- DIAPH2 | c.3241+39988C>T | Intron (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100231884; called by muse, mutect2, varscan2
- HELZ2 | c.1731-12C>T | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100915487; called by muse, mutect2, varscan2
- MACF1 | c.15832-9216A>G | Intron (SNP) | VAF 14/28 reads (50%) | catalogued as COSV57105755; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671135 C>T | 3'Flank (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- NACA | c.71-3859C>T | Intron (SNP) | VAF 70/112 reads (63%) | catalogued as COSV100771184; called by muse, mutect2, varscan2
- OR2W5 | n.1257G>A | RNA (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- P3H1 | c.2055+82C>T | Intron (SNP) | VAF 35/78 reads (45%) | catalogued as COSV52531610; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145828013 A>G | 3'Flank (SNP) | VAF 17/25 reads (68%) | catalogued as COSV59423087; called by muse, mutect2, varscan2
- UBQLN4 | c.*2C>T | 3'UTR (SNP) | VAF 87/191 reads (46%) | catalogued as rs1452169883, COSV100849297; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23366G>A | Intron (SNP) | VAF 70/149 reads (47%) | catalogued as rs898129248, COSV59381782; called by muse, mutect2, varscan2
